MMRF case MMRF_2284 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4b8af8dd-e4e6-4d2e-b49b-f62827341f05

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.9 years (24,818 days); ISS stage: II; Days to last known disease status: 785 days (2.1 years); Days to last follow up: 785 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 132 days; Days to treatment end: 132 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 771 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27: M Protein 3.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 136 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 41.7 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 5.21 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.52 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.58 mmol/L; Albumin 36 g/L; Total Protein 9.9 g/dL; Glucose 6.49 mmol/L; C-Reactive Protein 0.441 mg/dL.
- Day 64: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 5.31 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 450 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 6.44 mmol/L.
- Day 161 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 7.04 mmol/L.
- Day 239 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 2.82 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 2.29 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 330: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 4.18 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 6.05 mmol/L.
- Day 407: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 4.54 g/L; Immunoglobulin A 5.64 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 6.71 mmol/L.
- Day 505 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 6.01 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.36 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 5.61 mmol/L.
- Day 617 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.36 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 5.2 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.
- Day 694 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 5.53 g/L; Immunoglobulin A 6.65 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.66 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 4.95 mmol/L.
- Day 785 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.4 mg/dL; Immunoglobulin G 6.23 g/L; Immunoglobulin A 6.71 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2.06 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.52 ×10⁹/L; Platelets 54 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -27: Weight: 89 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2284_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2284_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
